Gene-level copy-number profile of tumor specimen TCGA-24-1419-01A from TCGA case TCGA-24-1419, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.0 years (22,659 days).
Specimen TCGA-24-1419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f3b49cf8-8541-4971-8e5b-960e35ae8686.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1419-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5155a974-9f1b-4b02-95e0-8e393946341a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,242; copy number 2: 39,334; copy number 3: 5,887; copy number 4: 65; copy number 6: 28; copy number 8: 15; copy number 13: 241.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1419-01A-01D-0472-01): tumor purity 0.98, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 284 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:72,280,969–73,258,798, 8 genes, copy number 6 (within-gene range 3–6): ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2.
- chr12:127,451,346–128,707,915, 27 genes, copy number 6–8 (within-gene range 4–8): AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC025160.1, AC087894.3, AC087894.2, AC087894.1, LINC02393, LINC00507, LINC00508, LINC02441, AC140121.1, LINC02369, LINC02368, AC061709.2, AC061709.1, TMEM132C, AC061709.3, MIR3612, AC023595.1, AC090424.1.
- chr14:104,085,686–106,824,147, 249 genes, copy number 6–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
